Somatic mutation profile of tumor specimen MP2PRT-PARNAV-TMP1-A (aliquot MP2PRT-PARNAV-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNAV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,649 days).
Specimen MP2PRT-PARNAV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4390a292-8bed-4b1a-894b-110857a76ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNAV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNAV-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dc19372-dea6-413b-bba6-e513d7cf7b49

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6115G>A p.E2039K | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs864622251, CM094668, COSV53740536, COSV53772321; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FRY | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66577738; called by muse, mutect2, varscan2
- GFRAL | c.951C>G p.F317L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99080205; called by muse, mutect2, varscan2
- MUC5B | c.15365C>T p.T5122M | Missense Mutation (SNP) | VAF 52/1035 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs774969000, COSV71594408; called by muse, mutect2
- OR2T33 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 206/676 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs370793191, COSV100532163; called by muse, mutect2, varscan2
- PSPN | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 478/1122 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201383020, COSV55532198; called by muse, varscan2
- ADAMTS20 | c.4057C>A p.Q1353K | Missense Mutation (SNP) | VAF 103/418 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.9842G>T p.G3281V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BCORL1 | c.3611C>G p.S1204C | Missense Mutation (SNP) | VAF 147/449 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GLT1D1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- IGKV1D-16 | chr2:90100738 TC>CGTCAGG | Missense Mutation (INS) | VAF 96/131 reads (73%) | called by pindel, varscan2*
- PCDH11X | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PCSK1N | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 494/1516 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- YY2 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 48/1177 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- ZBTB21 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 20/732 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2
- ZNF157 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KRTAP21-3 | c.9C>T p.F3= | Silent (SNP) | VAF 15/262 reads (6%) | catalogued as rs1273712858; called by muse, mutect2
- NRXN3 | c.324G>A p.T108= (on ENST00000557594 / NM_001272020.2; = p.T740= on NM_004796.6) | Silent (SNP) | VAF 303/718 reads (42%) | catalogued as rs200794295; called by muse, mutect2, varscan2
- PCDHA12 | c.1296G>C p.S432= | Silent (SNP) | VAF 228/849 reads (27%) | called by muse, mutect2, varscan2
- PDZD7 | c.1920C>G p.L640= | Silent (SNP) | VAF 189/746 reads (25%) | called by muse, mutect2, varscan2
- PROX1 | c.1284G>A p.Q428= | Silent (SNP) | VAF 30/936 reads (3%) | called by muse, mutect2
- RGPD4 | c.4236T>C p.T1412= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as rs1449520435; called by muse, mutect2, varscan2
